Gene-level copy-number profile of tumor specimen TCGA-CQ-6228-01A from TCGA case TCGA-CQ-6228, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 71.0 years (25,942 days).
Specimen TCGA-CQ-6228-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.8383139c-78ce-4fec-ace5-479cb3ca3c8e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-6228-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8b5f6c32-4a15-41f4-b3e9-aa8e610fb1e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 11,733; copy number 2: 40,863; copy number 3: 5,959; copy number 4: 547; copy number 5: 266; copy number 6: 36; copy number 8: 5; copy number 9: 83; copy number 10: 7; copy number 11: 1; copy number 12: 26; copy number 13: 154; copy number 16: 50; copy number 27: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-6228-01A-11D-1910-01): tumor purity 0.85, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:150,264,435–151,015,727, 1 gene (within-gene range 0–1): LRBA.
- chr4:150,579,089–150,721,478, 3 genes: AC110813.1, MAB21L2, ZBTB8OSP1.
- chr12:48,105,139–48,628,836, 32 genes: PFKM, MIR6505, ASB8, AC074029.3, AC074029.2, PHBP18, AC074029.1, CCDC184, AC074029.4, AC024257.3, OR10AD1, AC024257.1, AC024257.5, H1-7, AC024257.2, ZNF641, AC090115.1, OR5BK1P, AC024257.4, OR5BT1P, OR5BJ1P, OR8S21P, OR8T1P, ANP32D, C12orf54, AC089987.2, RPS10P20, AC089987.1, OR8S1, OR5BS1P, LALBA, OR11M1P.
- chr12:48,654,382–48,654,530, 2 genes: SNORA2C, MIR1291.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 668 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:96,244,732–96,814,407, 10 genes, copy number 5: AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1.
- chr8:124,450,820–139,127,953, 176 genes, copy number 5 (broad region; genes not listed).
- chr10:53,291,072–55,627,942, 8 genes, copy number 5 (within-gene range 3–5): AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1.
- chr10:80,247,219–81,137,335, 17 genes, copy number 5: EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14, AC021028.1, SH2D4B, LINC02655, RPS7P9, AC027673.1, FARSBP1, WARS2P1, RPA2P2.
- chr11:68,460,731–71,252,577, 67 genes, copy number 6–13 (within-gene range 1–13) (broad region; genes not listed).
- chr11:92,161,106–94,181,968, 55 genes, copy number 8–16 (within-gene range 1–16): RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1, AP003969.2, DEUP1, SMCO4, SRP14P2, RN7SL223P, AP003499.5, AP003499.4, AP003499.1, CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2, MED17, VSTM5, Y_RNA, AP002795.1, HPRT1P3, HEPHL1, PHBP16, PANX1.
- chr11:101,765,935–103,092,194, 40 genes, copy number 11–27: AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2.
- chr11:103,252,217–103,293,705, 1 gene, copy number 27 (within-gene range 1–27): AP002961.1.
- chr12:45,718,046–47,968,878, 55 genes, copy number 5: AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1, AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C.
- chr15:92,471,654–94,483,952, 42 genes, copy number 10–13 (within-gene range 2–13): C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5, FAM174B, AC091544.3, AC091544.7, AC091544.6, HMGN1P38, H2AZ2P1, AC091544.1, AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175, RGMA, YBX2P2, AC108457.1, AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2, AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2.
- chr15:95,326,528–100,544,995, 97 genes, copy number 13 (within-gene range 2–13) (broad region; genes not listed).
- chr17:37,489,891–39,977,768, 100 genes, copy number 9–12 (within-gene range 1–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,733. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
